Surgical pathology report (de-identified scan), TCGA case TCGA-27-2518, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-2518-01A (Primary Tumor).

[Redacted]

[Redacted]

[Redacted]

CGA-27-2518

Ref. Number

[Redacted]

Gender

[Redacted]

Birth date

[Redacted]

Tumor site

Left frontal

Histological diagnosis

Glioblastoma multiforme

[Redacted]

[Redacted]

[Redacted]

Source: NCI Genomic Data Commons file 252178de-2980-4744-84fc-acfa3378b5e5 (TCGA-27-2518.50376F0F-063E-4C47-BD08-EFF5ED594804.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).